Somatic mutation profile of tumor specimen PCProject_0125_T1_WES (aliquot PCProject_0125_T1_WES_1) from CMI case PCProject_0125, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.0 years (24,094 days).
Specimen PCProject_0125_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd823c1f-7262-499b-9fea-59f328fe56d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0125_SALIVA (Saliva), aliquot PCProject_0125_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07652663-6c18-44bd-942c-9c5f021ce322

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRRC2C | c.1687C>A p.Q563K (on ENST00000367742; = p.Q561K on NM_015172.4) | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs868576903; called by mutect2, varscan2
- ADM2 | c.*382C>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs751493325, COSV53313745; called by mutect2, varscan2
- NAAA | c.998+1031C>A | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs1489335399; called by mutect2, varscan2
- SLC4A8 | c.2172+4996A>G | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
